Somatic mutation profile of tumor specimen TCGA-HN-A2NL-01A (aliquot TCGA-HN-A2NL-01A-11D-A18P-09) from TCGA case TCGA-HN-A2NL, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.1 years (20,483 days).
Specimen TCGA-HN-A2NL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8194ee9b-8e7d-4202-aeb3-a4d3836cb15a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HN-A2NL-10A (Blood Derived Normal), aliquot TCGA-HN-A2NL-10A-01D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/142a5e13-fe0a-4cc4-9802-32acdf390e2e

The open-access MAF lists 82 somatic variants for this specimen: 65 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 52, Silent 17, Nonsense Mutation 3, Splice Region 3, Frame Shift Del 2, Frame Shift Ins 2, In Frame Del 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABAT | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 39/51 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762137050, COSV51621604; called by muse, mutect2, varscan2
- ABCA12 | c.4078G>T p.A1360S (on ENST00000272895 / NM_173076.3; = p.A1042S on NM_015657.3) | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99791159; called by muse, mutect2, varscan2
- AFAP1 | c.1955C>G p.T652S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); catalogued as COSV100631912; called by muse, mutect2, varscan2
- ANAPC4 | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100194167; called by muse, mutect2, varscan2
- ANGPTL7 | c.888C>G p.N296K | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100816507; called by muse, mutect2, varscan2
- ARSH | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as rs907740496, COSV66963179; called by muse, mutect2, varscan2
- BAIAP2L1 | c.97C>A p.L33M | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.999); catalogued as COSV99134538; called by muse, varscan2
- CHST15 | c.922T>C p.Y308H | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV100655268; called by muse, mutect2, varscan2
- CLDN2 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs1343608436, COSV61020576; called by muse, mutect2, varscan2
- COL11A1 | c.1558C>A p.L520I | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV100617651; called by muse, mutect2, varscan2
- CSTF2 | c.1184G>T p.R395M | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.846); catalogued as COSV100880824; called by muse, mutect2, varscan2
- CUL9 | c.3837G>T p.K1279N | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99335764; called by muse, mutect2, varscan2
- DCTN6 | c.374T>C p.I125T | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs372379363, COSV99645089; called by muse, mutect2, varscan2
- DDIAS | c.2789C>T p.T930M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs147890809; called by muse, mutect2, varscan2
- DPYS | c.764C>A p.A255D | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100679930; called by muse, mutect2
- DSC1 | c.165T>G p.C55W | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99937927; called by muse, mutect2
- E2F2 | c.252G>T p.P84= | Splice Region (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100674824, COSV100674842; called by muse, mutect2, varscan2
- EGR2 | c.899C>A p.A300E | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT tolerated (0.47); PolyPhen benign (0.137); catalogued as COSV99654227; called by muse, mutect2, varscan2
- FOLH1 | c.1219A>G p.K407E | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV99923605; called by muse, mutect2, varscan2
- GPR107 | c.1547A>G p.K516R (on ENST00000372406 / NM_001136557.2; = p.K468R on NM_020960.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT tolerated (0.23); PolyPhen benign (0.286); catalogued as rs368664209; called by muse, mutect2, varscan2
- HMGB4 | c.266A>T p.D89V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs917100126, COSV104384985, COSV99593070; called by muse, mutect2, varscan2
- IGSF10 | c.5950G>A p.D1984N | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.265); catalogued as rs753445759, COSV99185314; called by muse, mutect2, varscan2
- KAZN | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as COSV101056713; called by muse, mutect2, varscan2
- KIF21A | c.3802G>C p.A1268P (on ENST00000361418 / NM_001378440.1; = p.A1255P on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100735555; called by muse, mutect2, varscan2
- KLHL7 | c.308A>G p.Y103C (on ENST00000339077 / NM_001031710.3; = p.Y55C on NM_018846.5) | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100178278; called by muse, mutect2, varscan2
- MAP3K2 | c.928A>G p.T310A | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV100789365; called by muse, mutect2, varscan2
- MARS1 | c.2635C>G p.L879V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100007541; called by muse, mutect2, varscan2
- MROH5 | c.1493C>A p.S498Y | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.978); catalogued as COSV101436080; called by muse, mutect2, varscan2
- MROH8 | c.999C>T p.N333= | Splice Region (SNP) | VAF 25/56 reads (45%) | catalogued as rs374479476; called by muse, mutect2, varscan2
- MUC6 | c.3422G>T p.G1141V | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV101424702; called by muse, mutect2, varscan2
- MX1 | c.1722G>A p.M574I | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV55820463; called by muse, mutect2, varscan2
- MYO15A | c.8606C>G p.S2869C | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99233771; called by muse, mutect2, varscan2
- MYOM1 | c.616A>T p.K206* | Nonsense Mutation (SNP) | VAF 24/534 reads (4%) | catalogued as COSV99867716; called by muse, mutect2
- NAF1 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as rs1446711518, COSV56806371; called by muse, mutect2, varscan2
- NAV3 | c.3304A>G p.I1102V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV57116122; called by muse, mutect2, varscan2
- NRAP | c.4475C>A p.T1492N (on ENST00000359988 / NM_001322945.2; = p.T1457N on NM_006175.4) | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV100748535; called by muse, mutect2, varscan2
- NWD1 | c.4203G>C p.Q1401H | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100343324; called by muse, mutect2, varscan2
- OR5I1 | c.539dup p.C181Lfs*2 | Frame Shift Ins (INS) | VAF 17/46 reads (37%) | catalogued as rs757816304; called by mutect2, pindel, varscan2
- PDE3A | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs920198569, COSV100762609; called by muse, mutect2, varscan2
- PROM2 | c.1931G>C p.G644A | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.074); catalogued as COSV100469233; called by muse, mutect2, varscan2
- RBM42 | c.1115G>T p.S372I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV99387121; called by muse, mutect2, varscan2
- RBM4B | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs944995817, COSV100026492; called by muse, mutect2, varscan2
- SLC2A11 | c.85G>C p.G29R (on ENST00000345044 / NM_001024938.4; = p.G36R on NM_030807.5) | Missense Mutation (SNP) | VAF 68/84 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99741671; called by muse, mutect2, varscan2
- SLC4A5 | c.1505T>A p.I502N | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV61028498; called by muse, mutect2, varscan2
- SLC5A10 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs751392060, COSV100525375; called by muse, mutect2, varscan2
- ST3GAL3 | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99495779; called by muse, mutect2, varscan2
- SUDS3 | c.297G>C p.M99I | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV101288576, COSV66916754; called by muse, mutect2, varscan2
- TP53 | c.412_427dup p.V143Gfs*11 | Frame Shift Ins (INS) | VAF 14/54 reads (26%) | catalogued as COSV52805154, COSV99470544; called by mutect2, varscan2
- TRO | c.3436A>T p.S1146C | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV99436215, COSV99436974; called by muse, mutect2, varscan2
- TRPM6 | c.1011G>C p.G337= | Splice Region (SNP) | VAF 23/67 reads (34%) | catalogued as COSV100666717; called by muse, mutect2, varscan2
- TTN | c.4997C>T p.T1666I (on ENST00000591111; = p.T1620I on NM_003319.4) | Missense Mutation (SNP) | VAF 35/45 reads (78%) | PolyPhen benign (0.36); catalogued as COSV60338316; called by muse, mutect2, varscan2
- TXNDC15 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100613612; called by muse, mutect2, varscan2
- UNC5B | c.928A>C p.K310Q | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100101068; called by muse, mutect2, varscan2
- VPS13C | c.4528C>A p.L1510M (on ENST00000644861 / NM_020821.3; = p.L1467M on NM_017684.5) | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV99829482; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1171C>G p.L391V | Missense Mutation (SNP) | VAF 78/86 reads (91%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99648453, COSV99648893; called by muse, mutect2, varscan2
- ZDBF2 | c.2168A>T p.Q723L | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100985215; called by muse, mutect2, varscan2
- ZNF513 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 66/93 reads (71%) | catalogued as COSV52008053; called by muse, mutect2, varscan2
- ZNF99 | c.1982C>T p.S661F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.315); catalogued as COSV101233904, COSV68055333; called by muse, mutect2, varscan2
- ZSCAN21 | c.510C>G p.H170Q | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV99461185; called by muse, mutect2, varscan2
- AGBL4 | c.848_889del p.L283_S296del | In Frame Del (DEL) | VAF 18/66 reads (27%) | called by mutect2, pindel
- ARHGAP24 | c.669del p.P224Lfs*26 (on ENST00000395184 / NM_001025616.3; = p.P131Lfs*26 on NM_031305.3) | Frame Shift Del (DEL) | VAF 23/35 reads (66%) | called by mutect2, pindel, varscan2
- KMT2D | c.6875_6881del p.L2292Hfs*28 | Frame Shift Del (DEL) | VAF 18/22 reads (82%) | called by mutect2, pindel, varscan2
- NF1 | c.4174-4_4179del p.X1392_splice (on ENST00000358273 / NM_001042492.3; = p.X1371_splice on NM_000267.3) | Splice Site (DEL) | VAF 17/23 reads (74%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.1127G>T p.C376F | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- TTN | c.35276_35277insCTC p.P11759_E11760insS (on ENST00000591111; = p.P10832_E10833insS on NM_133378.4 and 1 other RefSeq transcript) | In Frame Ins (INS) | VAF 27/34 reads (79%) | called by mutect2, pindel, varscan2
- BPIFB4 | c.1107G>A p.P369= | Silent (SNP) | VAF 34/66 reads (52%) | catalogued as rs1316025830, COSV100971603; called by muse, mutect2, varscan2
- CCL24 | c.159C>A p.S53= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs782284631, COSV56116149; called by muse, mutect2, varscan2
- CEP250 | c.6177G>A p.Q2059= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs112052000; called by muse, mutect2, varscan2
- FBXO45 | c.231G>A p.E77= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV100218052, COSV100218119; called by muse, mutect2, varscan2
- FKBP4 | c.975G>A p.L325= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99133898; called by muse, mutect2, varscan2
- GUCY2D | c.1578G>T p.G526= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99644172, COSV99644379; called by muse, mutect2, varscan2
- IHH | c.63G>T p.V21= | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as COSV99838743; called by mutect2, varscan2
- MACF1 | c.15672T>C p.R5224= (on ENST00000372915; = p.R3157= on NM_012090.5) | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV99245878; called by muse, mutect2, varscan2
- MRPS2 | c.687C>T p.P229= | Silent (SNP) | VAF 21/23 reads (91%) | catalogued as COSV99613586; called by muse, mutect2, varscan2
- MYO16 | c.3504T>C p.L1168= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV100696964; called by muse, mutect2, varscan2
- OR5B3 | c.570A>G p.R190= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV100512041; called by muse, mutect2, varscan2
- PDPR | c.1689T>C p.T563= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as rs763563544, COSV99848634; called by muse, mutect2, varscan2
- PLA2R1 | c.2481T>C p.H827= | Silent (SNP) | VAF 48/53 reads (91%) | catalogued as COSV99323286; called by muse, mutect2, varscan2
- TRDN | c.159C>A p.V53= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as rs780737079, COSV100522919; called by muse, mutect2, varscan2
- TSHZ3 | c.2607C>T p.S869= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs751939179, COSV53663929; called by muse, mutect2, varscan2
- TXNDC15 | c.411A>C p.G137= | Silent (SNP) | VAF 23/29 reads (79%) | catalogued as COSV100613611; called by muse, mutect2, varscan2
- ZNF512B | c.1923C>G p.S641= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99412474; called by muse, mutect2, varscan2
